Somatic mutation profile of tumor specimen TCGA-BR-8682-01A (aliquot TCGA-BR-8682-01A-11D-2394-08) from TCGA case TCGA-BR-8682, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.5 years (19,165 days).
Specimen TCGA-BR-8682-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37db8fb8-705c-4d33-ab3e-3977bc60bbe0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8682-10A (Blood Derived Normal), aliquot TCGA-BR-8682-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a57fd1f-73a6-48c1-b3ad-3d3b68113b78

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, Nonsense Mutation 7, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZHX3 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 21/161 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs201454849, CM121425, COSV58380689; called by muse, mutect2, varscan2
- ANO2 | c.2837T>G p.F946C (on ENST00000356134 / NM_001278597.3; = p.F950C on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59047655; called by muse, mutect2, varscan2
- C10orf71 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368058122, COSV100110672; called by muse, mutect2, varscan2
- C10orf71 | c.1386C>A p.S462R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs559200171, COSV60503945; called by muse, mutect2, varscan2
- C8B | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as rs1251031526, COSV64780086; called by muse, mutect2, varscan2
- CAV1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372416448; called by muse, mutect2, varscan2
- CFAP161 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs756224699, COSV54429367; called by muse, mutect2
- CPNE8 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as rs1161451320, COSV58839617; called by muse, mutect2, varscan2
- DCLK1 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs754265976, COSV55209710; called by muse, mutect2, varscan2
- FIGNL1 | c.719T>A p.V240E | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV63554234; called by muse, mutect2, varscan2
- GGN | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as COSV53058187; called by muse, mutect2, varscan2
- GRIA1 | c.1555A>T p.K519* | Nonsense Mutation (SNP) | VAF 25/109 reads (23%) | catalogued as COSV53628865; called by muse, mutect2, varscan2
- HECTD4 | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs750765727, COSV61181990; called by muse, mutect2, varscan2
- IQCN | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs746376071, COSV66578955; called by muse, mutect2, varscan2
- IRF1 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 22/393 reads (6%) | catalogued as COSV55378672; called by muse, mutect2
- KAT7 | c.1509A>C p.K503N | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52015087, COSV52017490; called by muse, mutect2, varscan2
- KIAA1210 | c.4745C>A p.A1582E | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV68180845; called by muse, mutect2, varscan2
- KLF3 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV54713018; called by muse, mutect2, varscan2
- LUC7L | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs777326009, COSV53461162; called by muse, mutect2, varscan2
- MOXD1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as rs768904208, COSV60942573; called by muse, mutect2, varscan2
- MYL9 | c.278A>C p.K93T | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV54073163; called by muse, mutect2
- NCOA3 | c.2467C>T p.H823Y | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV59074466; called by muse, mutect2, varscan2
- NCR2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs142832518; called by muse, mutect2, varscan2
- NEBL | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs776191648, COSV65805196; called by muse, mutect2, varscan2
- NLRC4 | c.1366A>G p.S456G | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as COSV61595226; called by muse, mutect2, varscan2
- OLFM1 | c.1240G>A p.V414I (on ENST00000371793 / NM_001282611.2; = p.V396I on NM_014279.5) | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); catalogued as rs766525119, COSV53277115; called by muse, mutect2, varscan2
- OR1M1 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs148262558; called by muse, mutect2, varscan2
- OR2T4 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs762848397, COSV63545295; called by muse, mutect2, varscan2
- PAK5 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as rs755247878, COSV62032760, COSV62040191; called by muse, mutect2, varscan2
- PHACTR2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1212040083, COSV59860243; called by muse, mutect2, varscan2
- PLCH1 | c.4948C>T p.R1650W (on ENST00000340059 / NM_001130960.2; = p.R1642W on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749296221, COSV58212112; called by muse, mutect2, varscan2
- PUM3 | c.1159A>G p.M387V | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs190147284; called by muse, mutect2
- RALYL | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs752038591, COSV72818742; called by mutect2, varscan2
- RFPL4B | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs142366862, COSV71437438; called by muse, mutect2, varscan2
- ROBO1 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs1431830142, COSV71395879; called by muse, mutect2, varscan2
- SIX4 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV53671914; called by muse, mutect2, varscan2
- SLC26A6 | c.1936G>A p.G646S | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV56576184; called by muse, mutect2, varscan2
- SLC30A6 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs755069292, COSV50872447; called by mutect2, varscan2
- SLC5A5 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs764878885, COSV55836123; called by muse, mutect2, varscan2
- TFB2M | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63621088; called by muse, mutect2, varscan2
- TMPRSS3 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as COSV52309015; called by muse, mutect2, varscan2
- TNXB | c.10497G>A p.T3499= (on ENST00000647633; = p.T3252= on NM_019105.8 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 6/27 reads (22%) | catalogued as rs753566265, COSV100926453, COSV64490833; called by muse, mutect2, varscan2
- TRADD | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV50758388; called by muse, mutect2
- TRPA1 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs757390701, COSV51572989; called by muse, mutect2, varscan2
- WASF3 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 67/427 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs746475574, COSV58964661; called by muse, mutect2, varscan2
- XKR7 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73813309; called by muse, mutect2, varscan2
- ZNF536 | c.3500C>T p.S1167L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.185); catalogued as COSV62826848; called by muse, mutect2
- ZNF569 | c.389dup p.S132Ffs*7 | Frame Shift Ins (INS) | VAF 11/58 reads (19%) | catalogued as rs752923644; called by mutect2, pindel, varscan2
- KRTAP4-12 | c.23_24del p.S8Cfs*4 | Frame Shift Del (DEL) | VAF 26/198 reads (13%) | called by pindel, varscan2
- MAP3K7 | c.298-6_304del p.X100_splice | Splice Site (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel
- PHKB | c.2046dup p.K683* | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- SEL1L3 | c.2558del p.F853Sfs*15 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- UNK | c.2042_2043del p.E681Gfs*6 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by pindel, varscan2
- AXIN1 | c.1566G>A p.A522= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs569298843, COSV51994749; called by muse, mutect2, varscan2
- BMP10 | c.951C>T p.N317= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs113361577; called by muse, mutect2, varscan2
- DENND2D | c.747C>T p.A249= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV62960378; called by muse, mutect2, varscan2
- DZIP1 | c.2493C>T p.G831= (on ENST00000347108; = p.G812= on NM_014934.5) | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs554454725, COSV61267065; called by muse, mutect2, varscan2
- FAM83H | c.1317C>T p.D439= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1554623148; called by muse, varscan2
- FMNL3 | c.588G>A p.A196= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs749638078, COSV53299993; called by mutect2, varscan2
- FOXE1 | c.384G>A p.A128= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as COSV64301149; called by muse, mutect2, varscan2
- FSTL4 | c.1689C>T p.D563= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs376421685; called by muse, mutect2, varscan2
- HEY2 | c.915G>A p.P305= | Silent (SNP) | VAF 48/177 reads (27%) | catalogued as rs756533636, COSV100856386, COSV64240052; called by muse, mutect2, varscan2
- INSR | c.2700C>T p.V900= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV57175286; called by muse, mutect2
- NRXN1 | c.2412C>G p.L804= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV58501682; called by muse, mutect2, varscan2
- PRAME | c.1173G>A p.T391= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as rs767124537, COSV67162649; called by muse, mutect2, varscan2
- PRKCH | c.1653C>T p.H551= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as rs758220032, COSV60647862; called by muse, mutect2
- SCTR | c.258G>A p.E86= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs1483584933, COSV50033244; called by muse, mutect2, varscan2
- STAT4 | c.507C>T p.D169= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs199940585; ClinVar: likely benign; called by muse, mutect2, varscan2
- TCTN3 | c.999T>A p.T333= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV56452381; called by muse, mutect2, varscan2
- TMEM150C | c.627C>T p.G209= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV71389689; called by muse, mutect2, varscan2
- TRAF7 | c.846C>T p.C282= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- WNT7A | c.150G>A p.A50= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs201623293, COSV53196482, COSV53202929; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849974 C>T | 5'Flank (SNP) | VAF 14/22 reads (64%) | catalogued as rs746015264; called by muse, mutect2, varscan2
